Surgical pathology report (de-identified scan), TCGA case TCGA-24-1563, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1563-01A (Primary Tumor).

[page 1 of 5]
24-1563

Other Related Clinical Data:

DIAGNOSIS: OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED EPITHELIAL TYPE (SEE COMMENT)

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING MESOVARIUM
- PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING DEEP CERVICAL SOFT TISSUE
- MILD CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- CYSTIC ATROPHY

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA BY DIRECT EXTENSION FROM SEROSAL IMPLANT
- MULTIPLE LEIOMYOMAS, INTRAMURAL AND SUBMUCOSAL

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- EXTENSIVE METASTATIC ADENOCARCINOMA
- ADHESIONS

[page 2 of 5]
[REDACTED]

PERITONEUM, CUL-DE-SAC, BIOPSY
- METASTATIC ADENOCARCINOMA

OMENTUM, OMENTECTOMY
- METASTATIC ADENOCARCINOMA

PELVIS, TUMOR, EXCISION
- METASTATIC ADENOCARCINOMA

MESENTERY, NODULE, EXCISION
- METASTATIC ADENOCARCINOMA

APPENDIX, APPENDECTOMY
- METASTATIC ADENOCARCINOMA INVOLVING SEROSAL ASPECT

LARGE INTESTINE, SIGMOID, TUMOR, EXCISION
- METASTATIC ADENOCARCINOMA

LARGE INTESTINE, SIGMOID, PARTIAL EXCISION
- METASTATIC ADENOCARCINOMA INVOLVING ONE RESECTION MARGIN

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Report Electronically Reviewed and Signed Out By [REDACTED]

Microscopic Description and Comment: Histologic sections from the left ovarian mass show a poorly differentiated Mullerian adenocarcinoma. The majority of the tumor is present in solid sheets and nests. Some of the tumor, however, exhibits definite glandular differentiation with occasional areas of back to back glands diagnostic of endometrioid differentiation. Other areas exhibit intraluminal complexity in the form of papilla with markedly pleomorphic nuclei and numerous atypical mitotic figures consistent with serous differentiation. Metastatic adenocarcinoma is present in and around the left fallopian tube, in a small nodule in the right mesovarium, extensively involving the serosal aspect of the uterus and deep paracervical tissue with superficial invasion of overlying myometrium, in the omentum, on the serosal aspect of the appendix, in a mesenteric nodule, in a sigmoid nodule, and in the pelvis. A segment of the sigmoid colon has been resected. This segment is unoriented but one resection margin exhibits metastatic adenocarcinoma.

History: The patient is [REDACTED] with a pelvic mass. [REDACTED] now undergoes evaluation under anesthesia, exploratory laparotomy, total abdominal hysterectomy, with bilateral salpingo-oophorectomy, omentectomy, appendectomy, sigmoid resection with re-anastomosis, and optimal tumor debulking.

Specimen(s) Received:

A: CUL-DE-SAC TUMOR
B: UTERUS, CERVIX, BSO
C: SIGMOID TUMOR
D: SIGMOID COLON
E: PELVIC TUMOR
F: MESENTERY NODULE
G: APPENDIX

[page 3 of 5]
[REDACTED]

H: OMENTUM

Gross Description Received are eight containers, each labeled with the patient's name. The first is further designated "cul de sac tumor." It contains a 1 x 1 x 1 cm aggregate of friable tan tissue. [REDACTED]

The second container is further designated "uterus, cervix, BSO." It contains a 200 gram uterine corpus with attached adnexae and attached cervix. The left adnexa is largely replaced by a 7 x 4 x 4 cm friable tan tumor mass. The tumor has a finely papillary appearance. Attached to the tumor is a 3 cm in diameter smooth-lined cyst. Grossly, the tumor appears to be adhered and possibly invading the serosal surface of the left uterine corpus. The fallopian tube, which measures 3 cm in length and 1 cm in diameter appears to be uninvolved, although it is adherent to the tumor mass. The right adnexa consists of a 2 x 1.5 x 0.8 cm firm white and tan ovary with multiple corpora albicans and a 4 cm in length and 0.8 cm in diameter fallopian tube. There does not appear to be any evidence of tumor in the fallopian tube or the ovary; however, in the mesovarium, there is a 0.5 cm firm white nodule. The uterine corpus which measures 4.5 cm superior-inferior, 4 cm cornu-cornu, and 4.5 cm anterior-posterior is adhered to the left ovarian mass. Furthermore, there are multiple nodules of tumor studding the serosal surface. The endometrial cavity measures 2.5 x 2 cm with an endometrial thickness of 0.2 cm. The endometrium sounds to a depth of 8 cm. The endometrial lining is remarkable for a 2 x 2 x 1 cm polyp protruding into the endometrial cavity. Sectioning of the polyp reveals a central core with a firm white lobulated appearance, measuring 2 x 1.2 x 0.5 cm. The core of this polyp appears to arise from the underlying myometrium and is consistent with a submucosal leiomyoma protruding into the lumen of the cavity with an intact endometrial lining overlying the leiomyoma. There are also other intramural and subserosal unremarkable leiomyomas present, ranging from 1 cm in greatest dimension to 1.6 cm in greatest dimension. The myometrium is 2 cm in thickness anteriorly and 1.4 cm in thickness posteriorly. The cervix, which measures 3 cm in length and 3 cm in diameter with a round os measuring 0.5 cm in diameter, appears to be unremarkable without evidence of papillary formations, masses or nodules. Labeled B1 - soft tissue in area of right parametrium; B2 - soft tissue in area of left parametrium; B3 - left ovarian tumor; B4 and B5 - ovarian tumor in relation to cyst; B6 - additional cyst; B7 - left fallopian tube; B8 - extension of tumor to anterior uterine serosa; B9 - extension of tumor to posterior uterine serosa; B10 - extension of tumor into myometrium; B11 and B12 - tumor invading myometrium and base of endometrial polyp/leiomyoma; B13 and B14 - rest of polyp/leiomyoma; B15 - anterior cervix; B16 - anterior lower uterine segment; B17 - additional anterior endometrium; B18 - posterior cervix; B19 - posterior lower uterine segment; B20 - additional posterior endometrium; B21 - additional serosal nodules; B22 - right ovary and fallopian tube; B23 - right mesovarian nodule; B24 - additional left cyst. [REDACTED]

The third container is further designated "sigmoid tumor." It contains a 4 x 4 x 4 cm aggregate of friable tan tumor. [REDACTED]

The fourth container is further designated "sigmoid colon." It contains an unoriented segment of bowel measuring 9 cm in length and 2 cm in diameter with a serosal surface that is extensively involved by friable tan tumor. The tumor appears to extend very close to the resection margin. The mucosal surface appears to be unremarkable. Labeled: D1 - one resection margin; D2 - other margin; D3 - random section with tumor. [REDACTED]

The fifth container is further designated "pelvic tumor." It contains a 1 x 1 x 0.5 cm aggregate of friable tan tumor. [REDACTED]

The sixth container is further designated "mesentery nodule." It contains two portions of 1 cm in diameter tissue covered with a glistening membrane. [REDACTED]

[page 4 of 5]
[REDACTED]

The seventh container is further designated "appendix." It contains an 8 cm in length and 0.5 cm in diameter portion of appendix grossly involved by tumor at the serosa of the tip. Labeled G1, appendix including resection margin. [REDACTED]

The eighth container is further designated "omentum." It contains a 29 x 8 x 0.5 cm portion of omentum grossly involved by multiple nodules of tumor ranging from 0.5 to 2.5 cm in greatest dimension. [REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is: Other (Mixed epithelial type: endometrioid and serous)
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Left ovary only - but also in mesovarium of right ovary
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
- 7 Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: 2.5 cm
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is: 0
18. The total number of metastatically-involved regional lymph nodes is: 0
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c		IIIC	
peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension			

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

[page 5 of 5]
[REDACTED]

THE STATUS OF DISTANT TUMOR SITES is classified as: [REDACTED] (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file b4e02d14-5f6a-4b39-b688-3786a54c0e14 (TCGA-24-1563.6FDEB714-439D-49D7-AAE0-99166A3E8EBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).